FM case AD155 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/81a542f6-ef30-461f-883d-8cd864e98267

Male, 54.5 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3). Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
